TCGA case TCGA-GH-A9DA — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: ABS - IUPUI. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/67195401-9099-4ca9-9790-f42bcb815289

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 27 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 27.8 years (10,160 days); Year of diagnosis: 2013; Method of diagnosis: Biopsy; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: MX; FIGO stage: Stage IB1; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 540 days (1.5 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 15; Lymphatic invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, postoperative (reason: Not Done per Treating Physician's Discretion); adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS, postoperative (reason: Not Done per Treating Physician's Discretion); adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 42 (preoperative): Days to imaging: 42 days; Imaging type: PET; Imaging result: Positive; Imaging anatomic site: Cervix Uteri; Imaging findings: Pelvic Lymph Node Involvement; Imaging suv: 11.6.
- Days to follow up: 274 days; Disease response: Tumor Free.
- Days to follow up: 540 days (1.5 years); Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Height: 170 cm.
- Timepoint category: Initial Diagnosis; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 3; Pregnancy outcome: Live Birth.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 6.5; Age at onset: 14.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-GH-A9DA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 230 mg.
  Slide TCGA-GH-A9DA-01A-02-TS2: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 15; Percent necrosis: 2; Percent stromal cells: 13; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 2.
- Sample TCGA-GH-A9DA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-GH-A9DA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 3; Pregnancies count miscarriage: 2; Total pregnancy count: 5; Tobacco smoking history indicator: 2; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: Yes; Lymphovascular invasion: Absent; Corpus involvement: Absent; New tumor event diagnosis indicator: No.
- Fdg or ct pet performed outcomes: Fedpet or ct results: Pelvic Nodes Present.
- Treatment, Radiation therapy info: Radiation treatment reason not completed: Not done per treating physician discretion.
- Treatment, Concurrent prescription treatment info: Chemo concurrent reason not given: Not done per treating physicians discretion.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Performance status other timing: routine follow-up visit; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 540 days; disease-specific survival: no event (censored), 540 days; disease-free interval: no event (censored), 540 days; progression-free interval: no event (censored), 540 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-GH-A9DA-01A-21D-A37M-01): tumor purity 0.74, ploidy 2.17, whole-genome doublings 0.
